Somatic mutation profile of tumor specimen 0D9QL8 from CCDI case PBBIMX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neoplasm, benign; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.5 years (542 days).
Specimen 0D9QL8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f9f273a-5803-4edc-851a-1948691700db.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0D9QL9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/af54b0db-68b1-4881-b577-36551a85baaa

The open-access MAF lists 21 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Intron 4, Silent 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARAP3 | c.2836G>A p.A946T | Missense Mutation (SNP) | VAF 88/249 reads (35%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.999); catalogued as rs756689716, COSV99499306; called by muse, mutect2, varscan2
- DICER1 | c.5127T>A p.D1709E | Missense Mutation (SNP) | VAF 218/259 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV58619194; called by muse, mutect2, varscan2
- DNAH3 | c.6731G>A p.G2244E | Missense Mutation (SNP) | VAF 157/400 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as rs1407650744; called by muse, mutect2, varscan2
- DPP4 | c.2057C>T p.S686L | Missense Mutation (SNP) | VAF 218/831 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1485308827; called by muse, mutect2, varscan2
- TULP1 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 78/453 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.65); catalogued as rs139588263; called by muse, mutect2, varscan2
- ARID5B | c.2825T>C p.V942A | Missense Mutation (SNP) | VAF 33/496 reads (7%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2
- HSPG2 | c.6059C>A p.A2020D | Missense Mutation (SNP) | VAF 133/317 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- ITGA5 | c.1375G>A p.A459T | Missense Mutation (SNP) | VAF 82/403 reads (20%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- KCNC2 | c.234C>G p.F78L | Missense Mutation (SNP) | VAF 10/163 reads (6%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0); called by muse, mutect2
- LAMA2 | c.638A>T p.E213V | Missense Mutation (SNP) | VAF 15/367 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MAMDC4 | c.956C>A p.A319D | Missense Mutation (SNP) | VAF 48/289 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PRIM1 | c.325G>C p.D109H | Missense Mutation (SNP) | VAF 82/495 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPN23 | c.4317+1G>C p.X1439_splice | Splice Site (SNP) | VAF 98/220 reads (45%) | called by muse, mutect2, varscan2
- SLC35A2 | c.863T>G p.V288G | Missense Mutation (SNP) | VAF 63/85 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- PISD | c.403C>T p.L135= (on ENST00000439502 / NM_001326412.1; = p.L101= on NM_014338.3) | Silent (SNP) | VAF 21/398 reads (5%) | called by muse, mutect2
- TBC1D10A | c.909C>T p.I303= | Silent (SNP) | VAF 27/494 reads (5%) | called by muse, mutect2
- TTN | c.102930T>C p.D34310= (on ENST00000591111; = p.D26886= on NM_003319.4) | Silent (SNP) | VAF 127/396 reads (32%) | called by muse, mutect2, varscan2
- BRMS1L | c.142+57T>C | Intron (SNP) | VAF 6/126 reads (5%) | called by muse, mutect2
- CTSF | c.213+90C>G | Intron (SNP) | VAF 19/40 reads (48%) | called by muse, mutect2, varscan2
- ITGAD | c.3160-14dup | Intron (INS) | VAF 27/155 reads (17%) | called by mutect2, varscan2
- PRLHR | c.-6-23G>T | Intron (SNP) | VAF 5/52 reads (10%) | called by muse, mutect2
